Somatic mutation profile of tumor specimen MBCProject_3159_T1_WES (aliquot MBCProject_3159_T1_WES_1) from CMI case MBCProject_3159, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct and lobular carcinoma; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 54.1 years (19,764 days).
Specimen MBCProject_3159_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node(s) Regional; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1a546daa-b09b-4be2-a1c5-4ad2d5aa82ae.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_3159_SALIVA (Saliva), aliquot MBCProject_3159_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9b0efe46-2c01-46b3-a3d5-52b7f318978d

The open-access MAF lists 56 somatic variants for this specimen: 38 protein-altering or splice-affecting, 9 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 9, Intron 4, 5'UTR 2, Nonsense Mutation 2, RNA 2, Splice Site 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGEF38 | c.458C>A p.S153* | Nonsense Mutation (SNP) | VAF 25/183 reads (14%) | catalogued as rs772410292; called by muse, mutect2, varscan2
- FUCA1 | c.517C>T p.R173W | Missense Mutation (SNP) | VAF 76/421 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs768069468; called by muse, mutect2, varscan2
- KRT8 | c.107C>T p.S36L | Missense Mutation (SNP) | VAF 161/601 reads (27%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs779675126, COSV53176576; called by muse, mutect2, varscan2
- MYT1L | c.2113G>A p.G705R | Missense Mutation (SNP) | VAF 24/326 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.731); catalogued as COSV101219155; called by muse, mutect2
- PDLIM4 | c.928G>A p.V310M | Missense Mutation (SNP) | VAF 48/272 reads (18%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.999); catalogued as COSV99516743; called by muse, mutect2, varscan2
- RHOT2 | c.880C>T p.P294S | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.817); catalogued as rs79934819; called by mutect2, varscan2
- SIX4 | c.868T>G p.S290A | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.84); catalogued as COSV53670157; called by muse, mutect2, varscan2
- UFSP1 | c.190G>T p.G64W | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1257824182; called by muse, mutect2, varscan2
- ZNF592 | c.1408C>G p.P470A | Missense Mutation (SNP) | VAF 12/182 reads (7%) | SIFT tolerated (0.72); PolyPhen benign (0.006); catalogued as COSV55438543; called by muse, mutect2
- ASS1 | c.820A>C p.I274L | Missense Mutation (SNP) | VAF 20/306 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.013); called by muse, mutect2
- CCDC6 | c.110G>C p.G37A | Missense Mutation (SNP) | VAF 19/296 reads (6%) | SIFT tolerated, low confidence (0.8); PolyPhen probably damaging (0.939); called by muse, mutect2
- CHRND | c.908C>G p.S303C | Missense Mutation (SNP) | VAF 17/320 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); called by muse, mutect2
- DUSP21 | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 19/220 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.94); called by muse, mutect2
- EIF3A | c.181C>G p.L61V | Missense Mutation (SNP) | VAF 5/97 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2
- FEM1A | c.1718A>T p.D573V | Missense Mutation (SNP) | VAF 101/538 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- GAS1 | c.293C>G p.S98C | Missense Mutation (SNP) | VAF 134/590 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- GRID1 | c.82G>A p.A28T | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- KRTAP29-1 | c.745C>A p.P249T | Missense Mutation (SNP) | VAF 6/148 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2
- MKNK2 | c.709G>A p.G237R | Missense Mutation (SNP) | VAF 70/295 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- MYLK | c.2490C>A p.D830E | Missense Mutation (SNP) | VAF 43/467 reads (9%) | SIFT tolerated (0.6); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- NAV1 | c.2797C>G p.L933V | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.64); PolyPhen benign (0.006); called by muse, mutect2
- NFASC | c.1628G>A p.C543Y (on ENST00000339876 / NM_001378329.1; = p.C554Y on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/256 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- PCDH9 | c.454C>T p.P152S | Missense Mutation (SNP) | VAF 5/94 reads (5%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); called by muse, mutect2
- PRRC2A | c.3242G>T p.G1081V | Missense Mutation (SNP) | VAF 8/180 reads (4%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.814); called by muse, mutect2
- RAB34 | c.44A>T p.E15V | Missense Mutation (SNP) | VAF 17/131 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- RCC2 | c.841C>G p.P281A | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.019); called by muse, mutect2
- RELN | c.6142G>T p.G2048W | Missense Mutation (SNP) | VAF 34/450 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SP9 | c.1198C>A p.R400S | Missense Mutation (SNP) | VAF 27/207 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SQLE | c.578A>G p.N193S | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT tolerated (0.45); PolyPhen benign (0.013); called by muse, mutect2
- TEX15 | c.7416C>A p.D2472E (on ENST00000256246; = p.D2855E on NM_001350162.2) | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- TG | c.7153G>T p.D2385Y | Missense Mutation (SNP) | VAF 15/213 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- TOM1L1 | c.124_143+7del p.X42_splice | Splice Site (DEL) | VAF 28/156 reads (18%) | called by mutect2, pindel
- TRAV8-4 | c.63G>T p.Q21H | Missense Mutation (SNP) | VAF 6/91 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); called by muse, mutect2
- TXK | c.1211T>A p.V404E | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- VIPR2 | c.1175G>C p.S392T | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.464); called by muse, mutect2, varscan2
- XRCC5 | c.1954G>T p.E652* | Nonsense Mutation (SNP) | VAF 15/101 reads (15%) | called by muse, mutect2, varscan2
- ZDHHC8 | c.1589G>T p.G530V | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- ZNF335 | c.1356-6_1359del p.X452_splice | Splice Site (DEL) | VAF 11/83 reads (13%) | called by mutect2, pindel, varscan2
- ANPEP | c.402G>C p.G134= | Silent (SNP) | VAF 15/140 reads (11%) | called by muse, mutect2, varscan2
- BATF3 | c.129A>G p.E43= | Silent (SNP) | VAF 36/230 reads (16%) | called by muse, mutect2, varscan2
- CCDC88B | c.3607C>T p.L1203= | Silent (SNP) | VAF 6/66 reads (9%) | called by muse, mutect2
- CDCA5 | c.429G>A p.K143= | Silent (SNP) | VAF 5/56 reads (9%) | called by muse, mutect2
- ENPP2 | c.153C>T p.P51= | Silent (SNP) | VAF 158/238 reads (66%) | catalogued as rs965643358, COSV50016318; called by muse, varscan2
- OLIG2 | c.660C>T p.P220= | Silent (SNP) | VAF 21/182 reads (12%) | called by muse, mutect2, varscan2
- PCDHB8 | c.1620G>A p.P540= | Silent (SNP) | VAF 72/1379 reads (5%) | catalogued as rs782750667, COSV50760974; called by muse, mutect2
- PTPRB | c.120G>C p.V40= | Silent (SNP) | VAF 18/139 reads (13%) | called by muse, varscan2
- SNX17 | c.636C>T p.D212= | Silent (SNP) | VAF 9/78 reads (12%) | catalogued as rs372965338; called by mutect2, varscan2
- AC005863.1 | n.339A>G | RNA (SNP) | VAF 10/150 reads (7%) | called by muse, mutect2
- C5orf60 | n.2358G>A | RNA (SNP) | VAF 11/192 reads (6%) | called by muse, mutect2
- CR1 | c.487+12244A>C | Intron (SNP) | VAF 16/450 reads (4%) | called by muse, mutect2
- CRHR2 | c.184+254A>C | Intron (SNP) | VAF 7/93 reads (8%) | called by muse, mutect2
- HPN | c.161-57G>T | Intron (SNP) | VAF 10/104 reads (10%) | called by muse, mutect2, varscan2
- KCNJ5 | c.-10-39A>G | Intron (SNP) | VAF 14/148 reads (9%) | called by muse, mutect2
- PTGFRN | c.-116G>T | 5'UTR (SNP) | VAF 74/247 reads (30%) | called by muse, mutect2, varscan2
- PUDP | c.-4C>T | 5'UTR (SNP) | VAF 155/276 reads (56%) | called by muse, mutect2, varscan2
- SLC5A8 | c.*2G>T | 3'UTR (SNP) | VAF 10/83 reads (12%) | called by muse, mutect2, varscan2
